Somatic mutation profile of tumor specimen TCGA-50-5045-01A (aliquot TCGA-50-5045-01A-01D-1625-08) from TCGA case TCGA-50-5045, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 57.4 years (20,961 days).
Specimen TCGA-50-5045-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfb7c0a5-0c5f-46e8-9f0c-f7c53330322b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5045-10A (Blood Derived Normal), aliquot TCGA-50-5045-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fa9482e-04e2-4a9d-b245-ed37eb5d0ba1

The open-access MAF lists 296 somatic variants for this specimen: 239 protein-altering or splice-affecting, 53 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 53, Nonsense Mutation 21, Frame Shift Del 8, Splice Site 5, Splice Region 3, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1, RNA 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6820-1G>C p.X2274_splice (on ENST00000358273 / NM_001042492.3; = p.X2253_splice on NM_000267.3) | Splice Site (SNP) | VAF 20/95 reads (21%) | catalogued as rs1060500266, CS1311545, CS134549, COSV62201674, COSV62227637; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1264-1G>T p.X422_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as COSV65312209; called by muse, mutect2, varscan2
- AC004593.2 | c.903C>A p.H301Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV56091519; called by muse, mutect2, varscan2
- ACO1 | c.266+1G>T p.X89_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as COSV59379534, COSV59381007; called by muse, mutect2
- ACTN2 | c.1547A>T p.Q516L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.892); catalogued as rs1272875116, COSV63974656; called by muse, mutect2, varscan2
- ACTRT2 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as COSV65759285; called by muse, mutect2, varscan2
- ADAMTSL3 | c.596G>T p.C199F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54446067; called by muse, mutect2
- ADAMTSL3 | c.994C>G p.Q332E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV54446085, COSV99716519; called by muse, mutect2
- ADCYAP1R1 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58445507; called by mutect2, varscan2
- ADCYAP1R1 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416412, COSV58443767; called by muse, mutect2, varscan2
- ADGRG4 | c.7649T>A p.M2550K | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54955086; called by muse, mutect2, varscan2
- AFF2 | c.3834C>G p.D1278E | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53987594; called by muse, mutect2, varscan2
- AGAP2 | c.2135C>A p.P712H (on ENST00000547588 / NM_001122772.2; = p.P376H on NM_014770.4) | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57727962; called by muse, mutect2
- AGRN | c.1807G>T p.G603* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV101038778, COSV65069293; called by muse, mutect2, varscan2
- AGRN | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101038779; called by muse, mutect2, varscan2
- ANO10 | c.1801G>T p.A601S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV52730851; called by muse, mutect2, varscan2
- AP5Z1 | c.1213A>T p.M405L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV62241554; called by muse, mutect2, varscan2
- APAF1 | c.1432del p.E478Kfs*26 (on ENST00000551964 / NM_181861.2; = p.E467Kfs*26 on NM_001160.3) | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as COSV59662017; called by mutect2, pindel, varscan2
- ARHGAP33 | c.1944A>G p.E648= | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as COSV50122397; called by muse, mutect2, varscan2
- ARID5B | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV54419475; called by muse, mutect2, varscan2
- BAIAP3 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181343, COSV100181374; called by muse, mutect2, varscan2
- BCL11B | c.2674G>T p.E892* (on ENST00000357195 / NM_001282237.2; = p.E821* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV61735334; called by muse, mutect2, varscan2
- C10orf90 | c.1842C>A p.S614R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs762552292, COSV52954187; called by mutect2, varscan2
- CACNA1F | c.3691G>T p.G1231C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV59904225; called by muse, mutect2, varscan2
- CACNA2D1 | c.2379G>T p.M793I (on ENST00000356253 / NM_001366867.1; = p.M781I on NM_000722.4) | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100666477; called by muse, mutect2
- CACNA2D1 | c.2378T>A p.M793K (on ENST00000356253 / NM_001366867.1; = p.M781K on NM_000722.4) | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100666479; called by muse, mutect2
- CCDC150 | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV55873949; called by muse, varscan2
- CCDC93 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV60121060; called by muse, mutect2, varscan2
- CCKAR | c.1045G>T p.G349* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV55161200; called by muse, varscan2
- CCNT2 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as COSV99750533; called by muse, mutect2, varscan2
- CD163L1 | c.3920C>A p.T1307N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV58015229; called by muse, mutect2, varscan2
- CD1B | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 20/179 reads (11%) | catalogued as COSV63804225; called by muse, mutect2, varscan2
- CDH10 | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52579298; called by muse, mutect2, varscan2
- CDH20 | c.1537C>A p.Q513K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV99405085; called by muse, mutect2
- CENPF | c.4397T>C p.L1466P | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65274629; called by muse, mutect2, varscan2
- CES5A | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV51865922; called by muse, mutect2, varscan2
- CETN1 | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.238); catalogued as COSV59121044; called by muse, mutect2, varscan2
- CHD5 | c.1935-1G>T p.X645_splice | Splice Site (SNP) | VAF 11/98 reads (11%) | catalogued as COSV52413413; called by muse, mutect2, varscan2
- CHERP | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52224124; called by muse, mutect2, varscan2
- CHTOP | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV52680010; called by muse, mutect2
- CLEC14A | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60562398; called by muse, mutect2, varscan2
- CLSPN | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV52050326; called by muse, mutect2, varscan2
- CNGA2 | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100323597; called by muse, mutect2, varscan2
- CNTNAP4 | c.1366G>T p.V456F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV56677802, COSV56701203; called by muse, mutect2, varscan2
- COL4A2 | c.3053G>T p.G1018V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64627785; called by muse, mutect2, varscan2
- COL6A6 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62016738, COSV62023934; called by muse, mutect2, varscan2
- CRYGC | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs764211247, COSV56408972; called by muse, mutect2, varscan2
- CSAG1 | c.63G>C p.Q21H | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV63400215; called by muse, mutect2, varscan2
- CTAG2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55995633, COSV99908914; called by muse, mutect2
- CTNNA2 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs1425512623, COSV58150054; called by muse, mutect2
- CYP11B1 | c.1496T>A p.F499Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52826694; called by muse, mutect2
- CYSLTR2 | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV56165717; called by muse, mutect2, varscan2
- DACT1 | c.1472G>T p.S491I | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV60020563; called by muse, mutect2, varscan2
- DCAF12L2 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 24/123 reads (20%) | catalogued as COSV63581407; called by muse, mutect2, varscan2
- DCAF4L1 | c.423C>A p.H141Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60787106; called by muse, mutect2, varscan2
- DPYSL5 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56511326; called by muse, mutect2, varscan2
- DST | c.15088G>T p.E5030* (on ENST00000361203 / NM_001374722.1; = p.E2618* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV55011440, COSV99759083; called by muse, mutect2, varscan2
- EFCAB13 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs763879131, COSV58946331; called by muse, mutect2, varscan2
- ENAM | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68535844, COSV68537082; called by muse, mutect2, varscan2
- ENPP2 | c.1373C>T p.P458L (on ENST00000075322 / NM_001040092.3; = p.P510L on NM_006209.5) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV50013980; called by muse, mutect2
- EPHA3 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1439127416, COSV100347023, COSV60703785; called by muse, mutect2
- FAM227B | c.887A>G p.Q296R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV54810221; called by muse, mutect2, varscan2
- FASTKD1 | c.1751A>T p.N584I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71624268; called by muse, mutect2, varscan2
- FAT1 | c.7421G>C p.S2474T | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.875); catalogued as COSV101499373, COSV71673601; called by muse, mutect2
- FBLN1 | c.1959C>A p.D653E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV59937583, COSV59942368; called by muse, mutect2, varscan2
- FCN2 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV52476787; called by muse, mutect2, varscan2
- FCRL3 | c.1349C>A p.S450Y | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.679); catalogued as COSV63840765, COSV63841174; called by muse, mutect2
- FERD3L | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs202202177, COSV51762449; called by muse, mutect2
- FH | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV63818106, COSV63818179; called by muse, mutect2, varscan2
- FLG | c.9761C>A p.P3254H | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1443883943, COSV64241101; called by muse, mutect2
- FLG | c.2323C>A p.H775N | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV64241103; called by muse, mutect2
- FRMD6 | c.1364T>A p.I455K (on ENST00000344768 / NM_001267046.2; = p.I447K on NM_152330.4) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV61087741; called by muse, mutect2
- FSCB | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.391); catalogued as COSV61217816; called by muse, mutect2
- GAB4 | c.1367G>T p.W456L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as COSV68753726; called by muse, mutect2
- GAB4 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68753729; called by muse, mutect2, varscan2
- GABRQ | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV64781789; called by muse, mutect2, varscan2
- GAL3ST2 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV99510878; called by muse, mutect2
- GALNT17 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61160314; called by muse, varscan2
- GALT | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV66592872; called by mutect2, varscan2
- GLI3 | c.2453G>T p.C818F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV67887954; called by muse, mutect2, varscan2
- GPR137 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV100464176; called by muse, mutect2, varscan2
- GRID2 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV56200233; called by muse, mutect2, varscan2
- GRIN2A | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58030811; called by muse, mutect2, varscan2
- HERC2 | c.5496G>T p.M1832I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV55321491; called by muse, varscan2
- HNF1A | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57461921; called by muse, mutect2, varscan2
- HS6ST3 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368326730; called by muse, mutect2, varscan2
- IL21 | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV52645407, COSV99144440; called by muse, mutect2
- INHBA | c.1114G>T p.V372F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54221282; called by muse, mutect2, varscan2
- ITGA4 | c.1634C>A p.T545K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.129); catalogued as COSV51999797; called by muse, mutect2, varscan2
- ITGBL1 | c.874G>T p.G292* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV101095278, COSV66008260; called by muse, mutect2
- KCNH8 | c.1856C>A p.S619* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100111187, COSV60462549; called by muse, mutect2
- KCNQ2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60433703; called by muse, mutect2, varscan2
- KDM4C | c.2293C>T p.L765F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV67185382; called by muse, mutect2, varscan2
- KLHL6 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.863); catalogued as COSV100384534, COSV58069785; called by muse, mutect2, varscan2
- KMT2A | c.7727A>G p.N2576S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs147223140; called by muse, mutect2, varscan2
- KRT28 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60684978; called by muse, mutect2
- KRT71 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); catalogued as COSV57290398; called by muse, mutect2
- LAMB4 | c.2428G>T p.G810W | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52718126; called by muse, mutect2
- LAMP5 | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55716019, COSV55716521; called by muse, mutect2, varscan2
- LCLAT1 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV58372486; called by muse, mutect2
- LRRC3B | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101185790; called by muse, mutect2, varscan2
- MACROD2 | c.1154C>T p.S385L (on ENST00000642719; = p.S357L on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.406); catalogued as COSV53978533; called by muse, mutect2, varscan2
- MAGEC2 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV55999103; called by muse, mutect2, varscan2
- MAML3 | c.3376G>T p.E1126* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV72208829, COSV72209017; called by muse, mutect2, varscan2
- MAP3K9 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101173592; called by muse, mutect2, varscan2
- MAST1 | c.2671C>A p.Q891K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.179); catalogued as COSV52246153; called by muse, mutect2, varscan2
- MLLT10 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV56995222, COSV56995475; called by muse, mutect2, varscan2
- MNX1 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV53318120; called by muse, mutect2
- MRE11 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60576431; called by muse, mutect2
- MTMR4 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050968; called by muse, mutect2
- MUC16 | c.9731C>A p.P3244Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV101199508; called by muse, mutect2, varscan2
- MYH13 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52820473, COSV52827079; called by muse, mutect2, varscan2
- MYH2 | c.3364G>C p.E1122Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV55437065; called by muse, mutect2, varscan2
- MYOC | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs557741584, COSV50674625; called by muse, mutect2
- MYOCD | c.1688T>A p.L563Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV58502839; called by muse, mutect2, varscan2
- MYT1L | c.2564C>G p.P855R | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV67718894; called by muse, mutect2, varscan2
- NAT1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100306507; called by muse, mutect2
- NAV3 | c.3562C>A p.R1188S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.83); catalogued as COSV57076949, COSV57096164; called by muse, mutect2, varscan2
- NETO1 | c.667A>T p.M223L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as COSV55005847; called by muse, varscan2
- NFASC | c.3638C>A p.T1213K (on ENST00000339876 / NM_001378329.1; = p.T1142K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58364494, COSV58375346; called by muse, mutect2, varscan2
- NOL4 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV52363040, COSV99305586; called by muse, mutect2
- NPY1R | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.149); catalogued as COSV56714298, COSV56715481; called by muse, mutect2
- NPY1R | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV56714308, COSV99649029; called by muse, mutect2, varscan2
- OGDHL | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV65102144; called by muse, mutect2
- OLFM3 | c.484C>A p.Q162K (on ENST00000338858 / NM_001288821.1; = p.Q142K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV58798283; called by muse, mutect2, varscan2
- OR14C36 | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV58600720, COSV58601130; called by muse, mutect2, varscan2
- OR2A25 | c.99C>A p.F33L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV101376378; called by muse, mutect2, varscan2
- OR2A25 | c.100T>A p.Y34N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV101376380; called by muse, mutect2, varscan2
- OR2G2 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 36/173 reads (21%) | catalogued as COSV100189673, COSV60740033; called by muse, mutect2, varscan2
- OR2H2 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV100589643, COSV63542650; called by muse, mutect2, varscan2
- OR4A15 | c.221C>A p.A74E | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV59035012; called by muse, mutect2, varscan2
- OR4M1 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV60061052, COSV60061487; called by muse, mutect2, varscan2
- OR5R1 | c.815A>T p.K272M | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768029809, COSV56572169; called by muse, mutect2, varscan2
- OR5R1 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56572174; called by mutect2, varscan2
- OR5T2 | c.973A>T p.N325Y | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57588941; called by muse, mutect2, varscan2
- ORC2 | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV52237612, COSV52238410; called by muse, mutect2, varscan2
- PABPC5 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100442305, COSV57039608; called by muse, mutect2
- PAPPA2 | c.293A>T p.D98V | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV62777439; called by muse, mutect2, varscan2
- PASK | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | catalogued as COSV52151995; called by muse, mutect2
- PBX3 | c.714A>T p.K238N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60731972; called by muse, mutect2, varscan2
- PCDHA13 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56497117; called by muse, mutect2, varscan2
- PCDHA4 | c.2027C>A p.P676Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.036); catalogued as COSV63540954; called by muse, mutect2
- PCDHA7 | c.1119C>A p.S373R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.666); catalogued as rs139807581, COSV65343743; called by muse, mutect2, varscan2
- PCDHB10 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53378240; called by muse, mutect2, varscan2
- PCDHB12 | c.1223C>A p.P408Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV53396166; called by muse, mutect2, varscan2
- PCDHGA2 | c.1441A>C p.S481R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV53938290; called by muse, mutect2, varscan2
- PIEZO2 | c.6593C>T p.T2198I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.727); catalogued as COSV53288778, COSV53288989; called by muse, mutect2, varscan2
- PKHD1 | c.5174G>T p.W1725L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61873399; called by muse, mutect2, varscan2
- PKP2 | c.1853T>G p.L618R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV50729989; called by muse, varscan2
- PLCB1 | c.2046T>A p.I682= | Splice Region (SNP) | VAF 19/82 reads (23%) | catalogued as COSV62048725; called by muse, mutect2, varscan2
- PLCZ1 | c.1293G>T p.V431= | Splice Region (SNP) | VAF 6/52 reads (12%) | catalogued as COSV56852074; called by muse, mutect2
- PLD5 | c.1508A>T p.Q503L (on ENST00000442594; = p.Q441L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV59143679; called by muse, mutect2, varscan2
- PLEKHG6 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs776235753, COSV50599976; called by muse, mutect2, varscan2
- PLPPR4 | c.1421C>A p.P474H | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100926714, COSV64566332; called by muse, mutect2
- POLQ | c.5399G>T p.S1800I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51750763; called by muse, mutect2, varscan2
- PPFIA1 | c.860T>A p.L287Q | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54134034; called by muse, mutect2, varscan2
- PPP1R3A | c.2473A>G p.M825V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771601778, COSV52881481; called by muse, mutect2, varscan2
- PREP | c.1837G>T p.G613C (on ENST00000369110; = p.G679C on NM_002726.5) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64869947; called by muse, mutect2, varscan2
- PRPF18 | c.434del p.G145Vfs*13 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | catalogued as COSV100187290, COSV60726270; called by mutect2, varscan2
- PRR4 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as COSV57392138; called by muse, mutect2, varscan2
- PRUNE1 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54846852; called by muse, mutect2, varscan2
- PTPN5 | c.1588C>A p.Q530K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs772382740, COSV100079577; called by muse, mutect2, varscan2
- PTPRC | c.998G>C p.C333S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV61410705; called by muse, mutect2, varscan2
- PTPRD | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61942558; called by muse, mutect2, varscan2
- PTX4 | c.501G>T p.R167S (on ENST00000447419 / NM_001328608.2; = p.R162S on NM_001013658.1) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99560379; called by mutect2, varscan2
- PZP | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV54359410; called by muse, mutect2, varscan2
- RAPGEF4 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV51387090; called by muse, mutect2, varscan2
- RFX6 | c.2015T>A p.L672Q | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV60584685; called by muse, mutect2, varscan2
- RNF144B | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV52569661; called by muse, mutect2
- ROBO2 | c.283A>T p.I95F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59909142; called by muse, mutect2, varscan2
- ROBO2 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV100166032; called by muse, mutect2, varscan2
- RP1L1 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs753792631, COSV66754523; called by muse, mutect2, varscan2
- RPL10L | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100022514; called by muse, mutect2, varscan2
- RSPRY1 | c.1131G>T p.W377C | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68027608; called by muse, mutect2, varscan2
- SATB2 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV53482950; called by muse, mutect2, varscan2
- SCN5A | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61122722; called by muse, mutect2, varscan2
- SH3BP5L | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as COSV100821994, COSV63538766; called by mutect2, varscan2
- SIGLEC8 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV58473517; called by muse, mutect2, varscan2
- SLC11A2 | c.290G>A p.R97H (on ENST00000394904 / NM_001379455.1; = p.R68H on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs773212190, COSV50370614; called by muse, mutect2, varscan2
- SLC39A6 | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV52368992; called by muse, mutect2
- SLITRK1 | c.1576C>A p.L526I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65675367; called by muse, mutect2, varscan2
- SMARCA2 | c.3225G>C p.M1075I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV61806934; called by muse, mutect2, varscan2
- SMCHD1 | c.5257G>T p.V1753F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55256375; called by muse, mutect2, varscan2
- SNTB2 | c.1065G>C p.K355N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV60348982; called by muse, mutect2, varscan2
- SORCS1 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV53862509, COSV53888722; called by muse, mutect2, varscan2
- SPATA21 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV59186645, COSV59188425; called by muse, mutect2, varscan2
- SPATA31D1 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV61195223; called by muse, mutect2
- SPICE1 | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.151); catalogued as COSV55620161; called by muse, mutect2
- SPOCK1 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56447410; called by muse, varscan2
- SPTA1 | c.6516G>T p.W2172C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63755355, COSV63758515; called by muse, mutect2
- STAC | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 16/166 reads (10%) | catalogued as COSV56209760, COSV56209987; called by muse, mutect2
- SYT9 | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV59617715; called by muse, mutect2, varscan2
- TENM1 | c.1157C>A p.S386* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs1220654712, COSV64431001; called by muse, mutect2, varscan2
- TESK2 | c.1682T>G p.I561R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59151691; called by muse, mutect2, varscan2
- THSD7A | c.1644G>T p.E548D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV70264213; called by muse, mutect2, varscan2
- TMEM132A | c.1044G>T p.W348C (on ENST00000453848 / NM_178031.3; = p.W349C on NM_017870.4) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.634); catalogued as COSV50004821; called by muse, mutect2
- TMEM26 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53262050; called by muse, mutect2
- TMF1 | c.2531G>T p.R844I | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV68374159; called by muse, mutect2, varscan2
- TP53 | c.625A>T p.R209* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs1429743956, CM971504, COSV52741360, COSV52840233, COSV53599366; called by muse, mutect2, varscan2
- TPI1 | c.817T>A p.S273T (on ENST00000229270; = p.S236T on NM_000365.6) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99222862; called by muse, mutect2, varscan2
- TPI1 | c.818C>A p.S273Y (on ENST00000229270; = p.S236Y on NM_000365.6) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99222867; called by muse, mutect2, varscan2
- TRIM24 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.517); catalogued as COSV100630865; called by muse, mutect2, varscan2
- TRPC5 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53289485; called by muse, mutect2, varscan2
- TSHR | c.1139C>A p.A380D | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV53319025; called by muse, mutect2, varscan2
- TTBK1 | c.3028G>T p.A1010S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV52490310, COSV52490809; called by muse, mutect2, varscan2
- TTC12 | c.1739G>T p.R580L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV100132924, COSV100133054; called by muse, mutect2, varscan2
- UMOD | c.1803G>T p.L601F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1181331307, COSV56775308; called by muse, mutect2
- USH2A | c.6837T>A p.D2279E | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV56363002; called by muse, mutect2, varscan2
- USP33 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV62469214; called by muse, mutect2
- USP7 | c.1510G>T p.D504Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61214399, COSV61214588; called by muse, mutect2
- VANGL2 | c.131T>G p.V44G | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV63604382; called by muse, mutect2, varscan2
- VWA3A | c.2641T>A p.C881S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV100240807, COSV55395337; called by muse, mutect2
- WDR47 | c.2246A>G p.H749R (on ENST00000369962 / NM_001142551.2; = p.H750R on NM_014969.5) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.962); catalogued as rs983796654, COSV63057871; called by muse, varscan2
- WDR49 | c.964C>A p.P322T (on ENST00000308378 / NM_001366158.1; = p.P663T on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); catalogued as COSV57707463; called by muse, mutect2, varscan2
- XIRP2 | c.9008G>T p.R3003L (on ENST00000628543; = p.R3178L on NM_152381.6) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs375622239, COSV54697110; called by muse, mutect2, varscan2
- XYLT1 | c.2621G>C p.S874T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV54483308; called by muse, mutect2, varscan2
- ZBTB44 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV63537124; called by muse, mutect2
- ZBTB9 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV101221744, COSV67702184; called by muse, mutect2, varscan2
- ZFP3 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100603743; called by muse, mutect2
- ZFP91 | c.1205G>A p.C402Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60158623; called by muse, mutect2, varscan2
- ZNF248 | c.8A>T p.K3I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV61997614; called by muse, mutect2, varscan2
- ZNF281 | c.2438A>T p.Q813L | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV99664167; called by muse, mutect2
- ZNF317 | c.766G>T p.G256W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56109446, COSV99927135; called by muse, mutect2, varscan2
- ZNF317 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56109454; called by muse, mutect2, varscan2
- ZNF419 | c.73-1G>T p.X25_splice | Splice Site (SNP) | VAF 13/73 reads (18%) | catalogued as rs765032014, COSV55658066, COSV99692071; called by muse, mutect2, varscan2
- ZNF695 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV60585760; called by muse, mutect2
- ZNF711 | c.879G>T p.M293I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as rs959853747, COSV99340938; called by muse, mutect2
- ZNF98 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs746418327, COSV63336173; called by muse, mutect2, varscan2
- BUB1 | c.846dup p.A283Cfs*3 | Frame Shift Ins (INS) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- CCKAR | c.1053del p.I352Ffs*22 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by pindel, varscan2
- GPR179 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- GUSB | c.1470_1471del p.D490Efs*36 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, varscan2
- MUC5AC | c.14065C>A p.L4689M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- PCDHB16 | c.2248del p.Q750Nfs*6 | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | called by mutect2, pindel, varscan2
- PRSS12 | c.2443_2446dup p.K816Tfs*18 | Frame Shift Ins (INS) | VAF 8/88 reads (9%) | called by mutect2, pindel
- SLITRK4 | c.669del p.L224* | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | called by mutect2, pindel, varscan2
- SPTA1 | c.4029del p.T1344Pfs*5 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- TMEM41A | c.704_714del p.P235Hfs*2 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- TRBV4-2 | c.96G>T p.M32I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.042); called by muse, mutect2
- ASXL3 | c.3171C>A p.I1057= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1212155745, COSV52458225, COSV99326399; called by muse, mutect2
- C6orf120 | c.303G>A p.P101= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100179118; called by muse, mutect2, varscan2
- CASR | c.732C>G p.S244= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as COSV56137012; called by muse, mutect2, varscan2
- CD101 | c.246C>T p.Y82= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs749117063, COSV56716794, COSV56721385; called by muse, mutect2, varscan2
- CELA3B | c.504C>T p.N168= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs771647068; called by mutect2, varscan2
- CLEC4F | c.222A>C p.V74= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs781847018, COSV55479135; called by muse, mutect2, varscan2
- CTTNBP2 | c.2169C>T p.V723= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV50398414; called by muse, mutect2, varscan2
- DAB1 | c.1551C>A p.T517= (on ENST00000371231; = p.T484= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs759661844, COSV64699796; called by mutect2, varscan2
- DDX60 | c.4380C>G p.L1460= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV67096542; called by muse, varscan2
- DES | c.634C>A p.R212= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV64660268; called by muse, mutect2, varscan2
- EFCAB6 | c.102A>T p.S34= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV53062368; called by muse, mutect2, varscan2
- EPB41L3 | c.2700G>T p.G900= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV59444556; called by muse, mutect2, varscan2
- EPYC | c.324G>C p.G108= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs1298548979, COSV53799582; called by muse, mutect2
- EVX1 | c.396C>A p.A132= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1003718445, COSV56085170; called by muse, mutect2, varscan2
- FAF1 | c.1548C>T p.R516= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV65638235; called by muse, mutect2, varscan2
- FAM83G | c.1929A>T p.P643= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV58757769; called by muse, mutect2, varscan2
- FIG4 | c.657G>T p.G219= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV57787217; called by muse, mutect2, varscan2
- GALNT2 | c.660G>T p.L220= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV64194552; called by muse, mutect2, varscan2
- GJA9 | c.447C>G p.L149= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs375468847, COSV62532089; called by muse, mutect2
- GPC5 | c.1338C>T p.V446= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV65595281; called by muse, mutect2, varscan2
- GPR61 | c.414G>T p.V138= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV68177624; called by muse, mutect2
- GRID2 | c.267C>G p.G89= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV56200227; called by muse, mutect2, varscan2
- HTR1B | c.798G>T p.S266= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV64051416; called by muse, mutect2, varscan2
- IGKV2D-30 | c.249C>A p.V83= | Silent (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2
- IL36G | c.381C>A p.T127= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV52078473; called by muse, mutect2, varscan2
- IMPG1 | c.465G>A p.Q155= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV64057335; called by muse, mutect2, varscan2
- KCNK12 | c.475C>T p.L159= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs777701419, COSV59945508; called by muse, varscan2
- LSAMP | c.288C>T p.L96= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV61288526; called by muse, mutect2
- LYAR | c.60G>A p.K20= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1291618594, COSV58642466, COSV58642673; called by muse, mutect2, varscan2
- MAN2A2 | c.1122C>T p.R374= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV64637289; called by muse, mutect2, varscan2
- MITF | c.1371G>C p.G457= (on ENST00000448226 / NM_006722.3; = p.G357= on NM_000248.4) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV58831134, COSV58835240; called by muse, mutect2, varscan2
- MRC1 | c.990G>T p.L330= | Silent (SNP) | VAF 25/303 reads (8%) | called by muse, mutect2
- MUC16 | c.9732A>G p.P3244= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV101199506; called by muse, mutect2, varscan2
- MUSK | c.2238C>T p.L746= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV51884903; called by muse, mutect2
- NPSR1 | c.1062G>T p.R354= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV100706170; called by muse, mutect2
- OR2A12 | c.822C>A p.S274= | Silent (SNP) | VAF 51/262 reads (19%) | catalogued as COSV68821365; called by muse, mutect2, varscan2
- OR2H2 | c.27C>A p.G9= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs777747927, COSV100589642; called by muse, mutect2, varscan2
- OR52A5 | c.525A>T p.T175= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV56615039; called by muse, mutect2
- OSR2 | c.438C>T p.P146= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV52556791; called by muse, mutect2, varscan2
- PITPNM2 | c.846G>A p.G282= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV54900110; called by muse, mutect2, varscan2
- PTPRZ1 | c.3009T>C p.S1003= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV66435664; called by muse, mutect2, varscan2
- PTPRZ1 | c.4356G>A p.Q1452= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101100595, COSV66435673; called by mutect2, varscan2
- SLC9A2 | c.2322C>A p.G774= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV52131527; called by muse, mutect2, varscan2
- SPACA1 | c.687C>T p.I229= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV52759690; called by muse, mutect2, varscan2
- SPINT1 | c.1461C>T p.F487= (on ENST00000344051 / NM_181642.3; = p.F471= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV59801819; called by muse, mutect2, varscan2
- STAB1 | c.5154T>C p.P1718= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV58735513; called by muse, mutect2, varscan2
- STK35 | c.1002A>T p.P334= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV55690410; called by muse, mutect2, varscan2
- TAF1C | c.312T>A p.T104= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV58986060; called by muse, mutect2
- TTYH2 | c.534G>T p.A178= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV53910145, COSV53911013; called by muse, mutect2, varscan2
- UTP15 | c.1377T>A p.V459= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57146125; called by muse, mutect2, varscan2
- ZIC4 | c.918C>A p.L306= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs750237984, COSV101268127, COSV67171510; called by muse, mutect2, varscan2
- ZNF518B | c.501C>T p.C167= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs959307942, COSV58722302; called by muse, mutect2, varscan2
- ZNF644 | c.1506G>T p.V502= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV61347525; called by muse, mutect2
- B4GALNT1 | c.*1815C>A | 3'UTR (SNP) | VAF 32/115 reads (28%) | catalogued as COSV57542514; called by muse, mutect2, varscan2
- MAGED2 | c.1272-204G>T | Intron (SNP) | VAF 39/208 reads (19%) | catalogued as COSV54497232, COSV99514513; called by muse, mutect2, varscan2
- PGK2 | c.-1G>C | 5'UTR (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100505433; called by muse, mutect2
- SNORD115-44 | n.1G>T | RNA (SNP) | VAF 19/222 reads (9%) | called by muse, mutect2
